Somatic mutation profile of tumor specimen C3N-01525-03 (aliquot CPT0095890070) from CPTAC case C3N-01525, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01525-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3fd5399-890b-468f-8209-5298c2594668.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01525-31 (Blood Derived Normal), aliquot CPT0095910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2e4a664-0b52-47aa-ac47-e5f9f50bd6d9

The open-access MAF lists 100 somatic variants for this specimen: 74 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 17, Frame Shift Del 5, Intron 5, Nonsense Mutation 5, 3'UTR 2, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.3341G>A p.R1114Q (on ENST00000357008 / NM_001363606.2; = p.R1127Q on NM_001273.5) | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039917, COSV58895679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 90/263 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1173154389; called by muse, mutect2, varscan2
- ARHGEF10L | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355345589; called by muse, mutect2, varscan2
- ARID3B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs753085247; called by muse, mutect2, varscan2
- ATP2A1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767886671; called by muse, mutect2, varscan2
- BEX2 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.966); catalogued as rs1471821591; called by mutect2, varscan2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2
- CAMTA1 | c.3553A>G p.S1185G | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs954409338; called by muse, mutect2, varscan2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 119/267 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, mutect2, varscan2
- EPHB6 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 138/772 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs201556658, COSV63892635; called by muse, mutect2, varscan2
- GRIA4 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs151104343; called by muse, mutect2, varscan2
- GRIK5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs201959426; called by muse, mutect2, varscan2
- HEPACAM | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 104/475 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs751732183, COSV53430381; called by muse, mutect2, varscan2
- HRNR | c.8408G>A p.S2803N | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs552697734; called by muse, mutect2, varscan2
- HSF4 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 159/534 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50456664; called by muse, mutect2, varscan2
- JAG1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 93/333 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as rs766370717; called by muse, mutect2, varscan2
- KANSL1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs376632173; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.9572T>G p.L3191R | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52661427; called by muse, mutect2, varscan2
- KIAA2026 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 87/334 reads (26%) | catalogued as rs1228518521; called by muse, mutect2, varscan2
- LGI2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs139692298, COSV66123183; called by muse, mutect2, varscan2
- MAMLD1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs1005490291; called by muse, mutect2, varscan2
- MAP1S | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749473307; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- NICN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748614806, COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NKTR | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 25/164 reads (15%) | catalogued as rs1479671676; called by muse, mutect2, varscan2
- NLRP4 | c.1496T>G p.L499W | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs907483906, COSV56708637, COSV56710687; called by muse, mutect2, varscan2
- NOS3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as rs767108240; called by muse, mutect2, varscan2
- NR5A1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs752292248, COSV65295683; called by muse, mutect2, varscan2
- OR10A7 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV58278864; called by muse, mutect2, varscan2
- OR8D1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs562758196, COSV63441771; called by muse, mutect2, varscan2
- PARP4 | c.2860T>C p.W954R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1420177812; called by muse, mutect2, varscan2
- PAX1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68271303; called by muse, mutect2, varscan2
- PCDHGB2 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs573308473, COSV53966534; called by muse, mutect2
- PIK3R1 | c.1685G>C p.R562P (on ENST00000521381 / NM_181523.3; = p.R292P on NM_181504.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57124822; called by muse, mutect2, varscan2
- PRMT8 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs747021868; called by muse, mutect2, varscan2
- PTEN | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 44/237 reads (19%) | catalogued as rs1554825210, COSV64291584, COSV64299810; called by mutect2, varscan2
- ROPN1L | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1190893461; called by muse, mutect2, varscan2
- RYR1 | c.9560G>A p.R3187Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1171145743; called by muse, mutect2
- SRC | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1479989919; called by muse, mutect2, varscan2
- STARD6 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs145044397, COSV104410849; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs755371712, COSV51513640; called by muse, mutect2, varscan2
- ARID1A | c.5465del p.P1822Hfs*61 | Frame Shift Del (DEL) | VAF 44/153 reads (29%) | called by mutect2, pindel, varscan2
- ARID5B | c.1431_1434del p.L478* | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- ASH1L | c.3679T>A p.F1227I | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- B4GALT1 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 98/338 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- C2orf68 | c.296_307del p.E99_S103delinsA | In Frame Del (DEL) | VAF 27/166 reads (16%) | called by mutect2, pindel, varscan2
- CHPF | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ERO1B | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSIP2 | c.9247G>T p.V3083F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLCE | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- HLA-DQA1 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.228); called by muse, mutect2
- HNRNPH3 | c.58_61dup p.R21Pfs*68 | Frame Shift Ins (INS) | VAF 17/147 reads (12%) | called by mutect2, pindel, varscan2
- KCNA7 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 137/508 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KCNH3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KMT2E | c.4373C>T p.T1458I | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MX1 | c.1951_1952del p.T651Afs*20 | Frame Shift Del (DEL) | VAF 36/204 reads (18%) | called by mutect2, pindel, varscan2
- MYO10 | c.2464A>T p.K822* | Nonsense Mutation (SNP) | VAF 40/181 reads (22%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- OTP | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PLSCR5 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RYR2 | c.4634C>A p.A1545E | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- SBF2 | c.1860+7del | Splice Region (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- SLC25A51 | c.163del p.L55Sfs*18 | Frame Shift Del (DEL) | VAF 21/161 reads (13%) | called by mutect2, pindel, varscan2
- SLC4A10 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SLC6A19 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 96/479 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAT5A | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIM | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP36L2 | c.548dup p.R184Afs*290 | Frame Shift Ins (INS) | VAF 239/875 reads (27%) | called by mutect2, pindel, varscan2
- ZIC3 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 80/298 reads (27%) | called by muse, mutect2, varscan2
- ZNF331 | c.1172_1178del p.A391Vfs*7 | Frame Shift Del (DEL) | VAF 38/161 reads (24%) | called by mutect2, pindel, varscan2
- ZNF624 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZNF865 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- BMP2 | c.264T>G p.G88= | Silent (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2
- EPHA2 | c.1191G>T p.V397= | Silent (SNP) | VAF 85/402 reads (21%) | called by muse, mutect2, varscan2
- FRMPD3 | c.2607G>A p.P869= | Silent (SNP) | VAF 82/327 reads (25%) | catalogued as rs1451679884; called by muse, mutect2, varscan2
- GALNT3 | c.588A>G p.E196= | Silent (SNP) | VAF 37/208 reads (18%) | called by muse, mutect2, varscan2
- HDAC4 | c.882C>T p.S294= | Silent (SNP) | VAF 55/261 reads (21%) | catalogued as rs911608166, COSV100612898; called by muse, mutect2, varscan2
- HPSE2 | c.1413C>A p.G471= | Silent (SNP) | VAF 12/389 reads (3%) | called by muse, mutect2
- ITPRID1 | c.1299G>A p.P433= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs1277567601; called by muse, mutect2, varscan2
- KLHL33 | c.255T>C p.P85= | Silent (SNP) | VAF 87/290 reads (30%) | called by muse, mutect2, varscan2
- MAP1A | c.3774C>T p.P1258= | Silent (SNP) | VAF 59/233 reads (25%) | called by muse, mutect2, varscan2
- MICAL1 | c.2658C>T p.D886= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- MTUS2 | c.2013G>A p.P671= | Silent (SNP) | VAF 45/150 reads (30%) | catalogued as rs1424838911, COSV70916627; called by muse, mutect2, varscan2
- NUBP2 | c.405G>A p.P135= | Silent (SNP) | VAF 58/263 reads (22%) | catalogued as rs144072283; called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 109/456 reads (24%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PCNX3 | c.1473G>A p.T491= | Silent (SNP) | VAF 90/359 reads (25%) | catalogued as rs887263138; called by muse, mutect2, varscan2
- QPCTL | c.1011C>T p.P337= | Silent (SNP) | VAF 46/145 reads (32%) | catalogued as rs777466140; called by muse, mutect2, varscan2
- SYCP2L | c.111T>C p.D37= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.786C>T p.A262= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- ELK1 | c.-84G>A | 5'UTR (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- FAM27E5 | n.177C>T | RNA (SNP) | VAF 57/288 reads (20%) | catalogued as rs771362103; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46044G>A | Intron (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- MMAB | c.*790G>T | 3'UTR (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- RBMX2 | c.173+10C>A | Intron (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- STRA6 | c.597+20G>A | Intron (SNP) | VAF 90/358 reads (25%) | catalogued as rs1246268008; called by muse, mutect2, varscan2
- TMCO1 | c.*1695T>C | 3'UTR (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- TMX2 | c.250+19T>G | Intron (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- YARS1 | c.58-35C>G | Intron (SNP) | VAF 67/281 reads (24%) | called by muse, mutect2, varscan2
